Somatic mutation profile of tumor specimen 0DNP4G from CCDI case PBCBRP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.0 years (732 days).
Specimen 0DNP4G: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7428f59f-ad4b-47d2-84d3-d0bab0b476c2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DNP4C (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/44418942-fbb9-480f-a104-12958531951d

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, RNA 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKAIN1 | c.154C>T p.R52W | Missense Mutation (SNP) | VAF 150/410 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.653); catalogued as rs775641340; called by muse, mutect2
- NLRP2 | c.1943G>A p.R648Q | Missense Mutation (SNP) | VAF 78/392 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs753846462; called by muse, mutect2, varscan2
- LHPP | c.98T>C p.I33T | Missense Mutation (SNP) | VAF 37/296 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- MSANTD2P1 | n.999G>A | RNA (SNP) | VAF 42/150 reads (28%) | catalogued as rs1348287150; called by muse, mutect2
- MUC19 | n.8613C>A | RNA (SNP) | VAF 31/513 reads (6%) | catalogued as rs1353709095; called by muse, mutect2
